Somatic mutation profile of tumor specimen TCGA-DD-AAEA-01A (aliquot TCGA-DD-AAEA-01A-11D-A40R-10) from TCGA case TCGA-DD-AAEA, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 65.8 years (24,027 days).
Specimen TCGA-DD-AAEA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7c00fae-9e70-4959-a09f-cbecd4d18c3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAEA-10A (Blood Derived Normal), aliquot TCGA-DD-AAEA-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48f1e274-ad23-4619-a5ae-cb8943cbf099

The open-access MAF lists 200 somatic variants for this specimen: 161 protein-altering or splice-affecting, 35 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 35, Splice Site 6, Frame Shift Del 6, Nonsense Mutation 3, Frame Shift Ins 3, Splice Region 2, In Frame Del 2, RNA 2, Nonstop Mutation 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>G p.I195S | Missense Mutation (SNP) | VAF 56/113 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as rs749221334, COSV100589004; called by muse, mutect2, varscan2
- ABCA6 | c.2151A>G p.I717M | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99447641; called by muse, mutect2, varscan2
- ACO2 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); catalogued as rs147763800; called by muse, mutect2, varscan2
- ADGRG2 | c.281T>C p.I94T (on ENST00000379869 / NM_001079858.3; = p.I91T on NM_005756.4) | Missense Mutation (SNP) | VAF 248/390 reads (64%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.585); catalogued as rs900501617, COSV100492654; called by muse, mutect2, varscan2
- AFAP1 | c.1645+1G>C p.X549_splice | Splice Site (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100632116; called by muse, mutect2, varscan2
- AFF4 | c.3314A>G p.Y1105C | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs775632721, COSV99535375; called by muse, mutect2, varscan2
- ALOX12B | c.543T>G p.I181M | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.157); catalogued as COSV100047691; called by muse, mutect2, varscan2
- ANKRD28 | c.1580A>G p.E527G | Missense Mutation (SNP) | VAF 106/342 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1183554841, COSV101080924; called by muse, mutect2, varscan2
- ANKRD34B | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100103649; called by muse, mutect2, varscan2
- AOX1 | c.203A>G p.H68R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV101022227; called by muse, mutect2, varscan2
- AOX1 | c.2864T>C p.M955T | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1181179532, COSV101022228; called by muse, mutect2, varscan2
- ARL6IP5 | c.12T>A p.N4K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV99833042; called by muse, mutect2, varscan2
- ATP13A1 | c.1329G>C p.E443D | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV99366574; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2213C>A p.T738K | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59474975; called by muse, mutect2, varscan2
- AXIN1 | c.359C>A p.A120D | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99250292; called by muse, mutect2, varscan2
- BPTF | c.1884T>G p.D628E | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV100076009; called by muse, mutect2, varscan2
- C4BPA | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.385); catalogued as rs768900889, COSV100891281; called by muse, mutect2, varscan2
- C4orf19 | c.281A>G p.H94R | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99448775; called by muse, mutect2, varscan2
- CATSPERZ | c.368T>C p.M123T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs372953044; called by muse, mutect2, varscan2
- CCDC172 | c.103C>G p.R35G | Missense Mutation (SNP) | VAF 92/275 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.882); catalogued as rs868026474, COSV100319718, COSV100319989, COSV60937199; called by muse, mutect2, varscan2
- CDC27 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99296281; called by muse, mutect2, varscan2
- CEP250 | c.1600A>G p.K534E | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV100699175; called by muse, mutect2, varscan2
- CFH | c.663A>G p.I221M | Missense Mutation (SNP) | VAF 73/289 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.361); catalogued as rs1259243201, COSV100661626; called by muse, mutect2, varscan2
- CHD1 | c.1292A>C p.K431T | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV99399873; called by muse, mutect2, varscan2
- CHMP1B | c.530G>C p.G177A | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99304146; called by muse, mutect2, varscan2
- CHMP2B | c.31G>T p.D11Y | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV99773677; called by muse, mutect2, varscan2
- CHST10 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99959235; called by muse, mutect2, varscan2
- CNDP2 | c.1297A>G p.M433V | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV60841093; called by muse, mutect2, varscan2
- CNTN1 | c.1199T>C p.I400T | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV100751890; called by muse, mutect2, varscan2
- COL9A1 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs145698301; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COQ5 | c.515T>G p.I172S | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99942507; called by muse, mutect2, varscan2
- CRYBG1 | c.3214A>G p.R1072G | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV100954616; called by muse, mutect2, varscan2
- CTNNA3 | c.1972G>A p.D658N | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.989); catalogued as rs1215420249, COSV101051517; called by muse, mutect2, varscan2
- DAAM1 | c.2240A>G p.H747R | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.833); catalogued as COSV100658652; called by muse, mutect2, varscan2
- DCHS1 | c.4877C>A p.S1626Y | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.326); catalogued as COSV100202563, COSV55030556; called by muse, mutect2, varscan2
- DEPDC5 | c.2672A>G p.Y891C (on ENST00000400246; = p.Y960C on NM_014662.5) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99836497; called by muse, mutect2, varscan2
- DNAH9 | c.10375T>A p.C3459S | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.024); catalogued as rs1287523530, COSV99307971; called by muse, mutect2, varscan2
- DUS3L | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1295086525, COSV100288203; called by muse, mutect2, varscan2
- E2F4 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs995060206, COSV100104245; called by muse, mutect2, varscan2
- EMC10 | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT tolerated (0.59); PolyPhen benign (0.281); catalogued as COSV100618544; called by muse, mutect2, varscan2
- FAP | c.1095C>A p.Y365* | Nonsense Mutation (SNP) | VAF 19/90 reads (21%) | catalogued as COSV51863441; called by muse, mutect2, varscan2
- FBN2 | c.2944T>C p.C982R | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99330518; called by muse, mutect2, varscan2
- FNDC7 | c.701T>C p.M234T | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1395872194, COSV99601681; called by muse, mutect2
- FPGT-TNNI3K | c.675G>A p.K225= | Splice Region (SNP) | VAF 19/57 reads (33%) | catalogued as rs1415041740, COSV100436868, COSV58564734; called by muse, mutect2, varscan2
- FZD9 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs1175866183, COSV100750913; called by muse, mutect2, varscan2
- GABRA6 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 36/258 reads (14%) | catalogued as COSV99195068; called by muse, mutect2, varscan2
- GALC | c.941A>G p.Y314C | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD162984, CM960684, COSV99730487; called by muse, mutect2, varscan2
- GCFC2 | c.217A>T p.S73C | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); catalogued as COSV100319722; called by muse, mutect2, varscan2
- GLUD1 | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99518407; called by muse, mutect2, varscan2
- GPR3 | c.760G>C p.G254R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100927549; called by muse, mutect2, varscan2
- GSTA5 | c.477C>G p.H159Q | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as COSV99489721; called by muse, mutect2, varscan2
- HAUS6 | c.1277A>G p.Y426C | Missense Mutation (SNP) | VAF 152/447 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1307542515, COSV65840341; called by muse, mutect2
- HECTD4 | c.8442A>T p.E2814D | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV101108369; called by muse, mutect2, varscan2
- HPN | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99385337; called by muse, mutect2, varscan2
- IGF2R | c.737G>C p.G246A | Missense Mutation (SNP) | VAF 92/252 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100808132; called by muse, mutect2
- ITCH | c.1692G>C p.Q564H (on ENST00000262650 / NM_001257137.3; = p.Q523H on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99393142; called by muse, mutect2, varscan2
- JAKMIP3 | c.1525T>C p.Y509H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100059880; called by muse, mutect2, varscan2
- KCNMB1 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99211980; called by muse, mutect2, varscan2
- KMT2E | c.682A>T p.R228W | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99996971; called by muse, mutect2, varscan2
- LGALS3BP | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as COSV99431924; called by muse, mutect2, varscan2
- LPIN2 | c.1711-2A>T p.X571_splice | Splice Site (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99858954; called by muse, mutect2, varscan2
- LRP1B | c.1409-1G>T p.X470_splice | Splice Site (SNP) | VAF 19/73 reads (26%) | catalogued as COSV101260591; called by muse, mutect2, varscan2
- LRP4 | c.3742T>A p.L1248M | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV101066866; called by muse, mutect2, varscan2
- LRRC2 | c.248C>G p.T83S | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99947661; called by muse, mutect2, varscan2
- MAGEL2 | c.3375C>A p.N1125K | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.425); catalogued as COSV100046202; called by muse, mutect2, varscan2
- MAPKBP1 | c.1160A>G p.Y387C (on ENST00000456763 / NM_001128608.2; = p.Y381C on NM_014994.3) | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99530126; called by muse, mutect2, varscan2
- MARK3 | c.2069A>G p.Y690C (on ENST00000429436 / NM_001128918.3; = p.Y666C on NM_002376.6) | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs760433327, COSV99358764; called by muse, mutect2, varscan2
- MC3R | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs770261378, CM074934, COSV54763303, COSV54763474; called by muse, varscan2
- MCEMP1 | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV100365441; called by muse, mutect2, varscan2
- MROH2B | c.2759T>C p.I920T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1254484939, COSV101270909; called by muse, mutect2, varscan2
- MRPS31 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); catalogued as COSV60267283; called by muse, mutect2, varscan2
- MUC16 | c.43457A>C p.E14486A | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as COSV101110080; called by muse, mutect2, varscan2
- MUC16 | c.41653C>A p.L13885M | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.993); catalogued as COSV101110081, COSV66692165; called by muse, mutect2
- NBEAL1 | c.7226A>G p.D2409G | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101355615; called by muse, mutect2, varscan2
- NEB | c.19018T>C p.Y6340H | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757420871, COSV99427748; called by muse, mutect2, varscan2
- NOXRED1 | c.982G>C p.V328L | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99375690; called by muse, mutect2, varscan2
- NPAS3 | c.1585G>A p.D529N (on ENST00000356141 / NM_001164749.2; = p.D497N on NM_022123.3) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs1244283612, COSV60846353; called by muse, mutect2, varscan2
- NR5A2 | c.479G>A p.R160Q (on ENST00000367362 / NM_205860.3; = p.R114Q on NM_003822.5) | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762746404, COSV99371664; called by muse, mutect2, varscan2
- NTRK3 | c.1184T>A p.F395Y | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100448018; called by muse, mutect2, varscan2
- NUP214 | c.3449C>A p.T1150K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV100845386; called by muse, mutect2, varscan2
- OR6C2 | c.220G>T p.V74F | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.061); catalogued as COSV100498757; called by muse, mutect2
- OR6C70 | c.92T>C p.L31P | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); catalogued as COSV100524512; called by muse, mutect2, varscan2
- PAK2 | c.8A>C p.D3A | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.211); catalogued as rs774861902, COSV100506334; called by muse, mutect2, varscan2
- PCDH15 | c.3274A>G p.N1092D | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV100227276; called by muse, mutect2, varscan2
- PGM2L1 | c.1639C>A p.P547T | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99995197; called by muse, mutect2
- PIEZO2 | c.6967C>T p.L2323F | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53287300; called by muse, mutect2, varscan2
- PPWD1 | c.866C>G p.S289* | Nonsense Mutation (SNP) | VAF 14/158 reads (9%) | catalogued as COSV54332832, COSV99731569; called by muse, mutect2
- PRDM11 | c.1303G>A p.D435N (on ENST00000530656 / NM_001359633.1; = p.D401N on NM_001256695.1) | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.11); catalogued as COSV99771095; called by muse, mutect2, varscan2
- PRDM5 | c.1018A>T p.I340F | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.996); catalogued as rs923137742, COSV99311361; called by muse, mutect2, varscan2
- PRG4 | c.4099T>A p.Y1367N | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100798313; called by muse, mutect2, varscan2
- PROM1 | c.154A>G p.I52V | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.268); catalogued as COSV101477129; called by muse, mutect2, varscan2
- PRSS48 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as rs1394957142, COSV101490185; called by muse, mutect2
- RAET1G | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1489274471, COSV100951696; called by muse, mutect2, varscan2
- RARRES1 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 63/243 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.02); catalogued as rs759534219, COSV52962718; called by muse, mutect2, varscan2
- RASGRP3 | c.700C>A p.Q234K | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV101274900, COSV67824625; called by muse, mutect2, varscan2
- RCCD1 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.164); catalogued as rs1260321168, COSV101263243; called by muse, mutect2, varscan2
- RERE | c.4276C>T p.H1426Y | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.996); catalogued as COSV100557282, COSV61936352; called by muse, mutect2, varscan2
- RPRD2 | c.1528A>G p.I510V | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.502); catalogued as COSV100955352; called by muse, mutect2, varscan2
- SAMD12 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100126845; called by muse, mutect2, varscan2
- SCAMP1 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 80/332 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV100210618; called by muse, mutect2, varscan2
- SCIN | c.1001G>C p.G334A (on ENST00000297029 / NM_001112706.3; = p.G87A on NM_033128.3) | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV99765287; called by muse, mutect2, varscan2
- SDK1 | c.5539G>C p.G1847R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV101269815; called by muse, mutect2, varscan2
- SELENOV | c.740C>A p.T247K | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.812); catalogued as COSV100112874; called by muse, mutect2, varscan2
- SH2D5 | c.1235A>T p.H412L (on ENST00000444387 / NM_001103161.2; = p.H328L on NM_001103160.2) | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); catalogued as COSV99929715; called by muse, mutect2, varscan2
- SHPRH | c.2090A>G p.K697R | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.725); catalogued as COSV99262658; called by muse, mutect2, varscan2
- SLC10A5 | c.506C>G p.T169R | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV101594272; called by muse, mutect2, varscan2
- SLC6A15 | c.2144G>A p.G715E | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV99030859; called by muse, mutect2, varscan2
- SLFN11 | c.2126A>G p.H709R | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs777668696, COSV100391005; called by muse, mutect2, varscan2
- SLU7 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99775822; called by muse, mutect2, varscan2
- SMARCA2 | c.4376A>G p.H1459R | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as rs1203661729, COSV100190963; called by muse, mutect2, varscan2
- SMC1A | c.2918A>G p.Y973C | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs781980688, COSV100447664; called by muse, mutect2, varscan2
- SNAPC3 | c.347A>T p.E116V | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV101072812; called by muse, mutect2
- SNUPN | c.797A>G p.Y266C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100419468; called by muse, mutect2, varscan2
- SNX11 | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100821799; called by muse, mutect2, varscan2
- SNX2 | c.485A>G p.Y162C | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101075831; called by muse, mutect2, varscan2
- SSH2 | c.4084G>A p.G1362R | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1379836440, COSV99282979; called by muse, mutect2, varscan2
- SUPT20H | c.2335T>C p.F779L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99524102; called by muse, mutect2, varscan2
- TANC2 | c.3034G>C p.D1012H | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV101267667, COSV67343493; called by muse, mutect2, varscan2
- TCF4 | c.223A>G p.T75A | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs567398278, COSV100610806; ClinVar: likely benign; called by muse, mutect2, varscan2
- TECTA | c.1655A>G p.Y552C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99881468; called by muse, mutect2, varscan2
- TET3 | c.1121C>G p.S374C | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV59883224; called by muse, mutect2, varscan2
- TIE1 | c.1184T>C p.L395P | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100992183, COSV65250713; called by muse, mutect2, varscan2
- TLR3 | c.1771A>G p.I591V | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.368); catalogued as COSV99711214; called by muse, mutect2, varscan2
- TNRC6A | c.4516A>G p.N1506D | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV100170454; called by muse, mutect2, varscan2
- TRA2A | c.755A>G p.Y252C | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.536); catalogued as rs765283544, COSV99767822; called by muse, mutect2, varscan2
- TRIM37 | c.2636C>A p.S879Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV99233428; called by muse, mutect2, varscan2
- TRPM7 | c.2564A>T p.K855I | Missense Mutation (SNP) | VAF 86/323 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100540307; called by muse, mutect2, varscan2
- TSPAN4 | c.64-2A>G p.X22_splice | Splice Site (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100060202; called by muse, mutect2, varscan2
- TTC33 | c.614A>T p.D205V | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100532101; called by muse, mutect2, varscan2
- TTI1 | c.1128A>C p.E376D | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100989749; called by muse, mutect2, varscan2
- UBE4A | c.771A>G p.I257M (on ENST00000252108 / NM_001204077.2; = p.I264M on NM_004788.4) | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs753300119, COSV99348577; called by muse, mutect2, varscan2
- UROC1 | c.1168A>G p.I390V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.361); catalogued as COSV99332344; called by muse, mutect2, varscan2
- USP34 | c.8374A>G p.I2792V | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.558); catalogued as rs749516059, COSV68403287; called by muse, mutect2, varscan2
- VANGL1 | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100049476; called by muse, mutect2, varscan2
- VPS13A | c.1901-1G>T p.X634_splice | Splice Site (SNP) | VAF 104/218 reads (48%) | catalogued as COSV100653495, COSV62433613; called by muse, mutect2, varscan2
- WTAP | c.623T>C p.I208T | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100603406; called by muse, mutect2, varscan2
- ZCCHC14 | c.1949C>T p.A650V (on ENST00000268616; = p.A787V on NM_015144.3) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); catalogued as COSV99234532; called by muse, mutect2, varscan2
- ZFYVE16 | c.3487G>T p.D1163Y | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100566636, COSV62017291; called by muse, mutect2, varscan2
- ZIM3 | c.170T>C p.V57A | Missense Mutation (SNP) | VAF 90/204 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.176); catalogued as COSV99518632; called by muse, mutect2
- ZMYM1 | c.2930A>G p.Q977R | Missense Mutation (SNP) | VAF 74/262 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV100721066; called by muse, mutect2, varscan2
- ZMYM5 | c.422G>T p.W141L | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.666); catalogued as COSV100562834; called by muse, mutect2, varscan2
- ZNF229 | c.1127C>A p.P376H | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99350920; called by muse, mutect2, varscan2
- ZNF668 | c.1751C>G p.A584G | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as COSV100336880, COSV56217188; called by muse, mutect2, varscan2
- ZNF740 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV99915026; called by muse, mutect2, varscan2
- C16orf82 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CCL16 | c.214A>C p.N72H | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CDC25B | c.1277del p.G426Afs*11 (on ENST00000245960 / NM_021873.3; = p.G412Afs*11 on NM_004358.4) | Frame Shift Del (DEL) | VAF 30/123 reads (24%) | called by mutect2, pindel, varscan2
- CLCN2 | c.1703dup p.G569Rfs*51 | Frame Shift Ins (INS) | VAF 26/102 reads (25%) | called by mutect2, pindel, varscan2
- CNTN3 | c.1024dup p.S342Kfs*39 | Frame Shift Ins (INS) | VAF 35/122 reads (29%) | called by mutect2, pindel, varscan2
- EPOR | c.1403_1417del p.Y468_D472del | In Frame Del (DEL) | VAF 13/50 reads (26%) | called by pindel, varscan2
- FAT1 | c.9348del p.D3117Mfs*2 | Frame Shift Del (DEL) | VAF 27/73 reads (37%) | called by mutect2, pindel, varscan2
- FBXW5 | c.1170_1174del p.F391Rfs*52 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- GMPPB | c.622del p.Y208Mfs*29 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | called by mutect2, pindel, varscan2
- HEATR6 | c.1875_1881del p.D625Efs*69 | Frame Shift Del (DEL) | VAF 50/125 reads (40%) | called by mutect2, pindel, varscan2
- KCTD6 | c.508_516del p.T170_D172del | In Frame Del (DEL) | VAF 42/170 reads (25%) | called by mutect2, pindel, varscan2
- LILRA6 | c.955+1G>T p.X319_splice | Splice Site (SNP) | VAF 39/212 reads (18%) | called by muse, mutect2
- NOL7 | c.771_*4del | Nonstop Mutation (DEL) | VAF 79/357 reads (22%) | called by mutect2, pindel, varscan2
- PCDHGA4 | c.1926del p.S643Afs*32 | Frame Shift Del (DEL) | VAF 13/120 reads (11%) | called by mutect2, pindel, varscan2
- PCDHGA9 | c.2424+8C>A | Splice Region (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- SAMHD1 | c.1397dup p.I468Dfs*2 | Frame Shift Ins (INS) | VAF 37/234 reads (16%) | called by mutect2, pindel, varscan2
- ARHGEF26 | c.1668A>G p.V556= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs370646022; called by muse, mutect2, varscan2
- ASB7 | c.273T>C p.H91= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as COSV100235345; called by muse, mutect2, varscan2
- CHD9 | c.2334A>G p.V778= | Silent (SNP) | VAF 93/286 reads (33%) | catalogued as COSV54610973; called by muse, mutect2, varscan2
- CTNNA3 | c.2316T>A p.I772= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV101041610; called by muse, mutect2, varscan2
- CTTNBP2 | c.2247T>C p.Y749= | Silent (SNP) | VAF 48/201 reads (24%) | catalogued as rs1340710674, COSV99354811; called by muse, mutect2, varscan2
- DCHS1 | c.792G>T p.V264= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as COSV100202565; called by muse, mutect2, varscan2
- DOT1L | c.4503G>A p.V1501= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV101288805; called by muse, mutect2, varscan2
- FMNL1 | c.1365C>A p.P455= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV100056926; called by muse, mutect2, varscan2
- G6PC | c.354C>G p.G118= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as rs766771010, COSV99520967; called by muse, mutect2, varscan2
- GPR183 | c.168T>A p.I56= | Silent (SNP) | VAF 51/183 reads (28%) | catalogued as COSV100854399; called by muse, mutect2, varscan2
- H4C8 | c.90C>T p.I30= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as COSV99175514; called by muse, mutect2, varscan2
- IL10 | c.534C>T p.N178= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as COSV65594815; called by muse, mutect2, varscan2
- ITCH | c.2649T>C p.Y883= (on ENST00000262650 / NM_001257137.3; = p.Y842= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV99393145; called by muse, mutect2, varscan2
- KIF13B | c.789A>G p.T263= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV101580794; called by muse, mutect2, varscan2
- LUZP2 | c.720C>A p.P240= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV100421293; called by muse, mutect2, varscan2
- MAOA | c.345A>G p.V115= | Silent (SNP) | VAF 40/70 reads (57%) | catalogued as COSV100108994; called by muse, mutect2, varscan2
- MAP3K2 | c.1758C>G p.V586= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as COSV100789392; called by muse, mutect2, varscan2
- MBNL1 | c.1065A>G p.T355= (on ENST00000282486 / NM_207293.2; = p.T349= on NM_021038.5 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 90/266 reads (34%) | catalogued as rs1553945384, COSV99221250; called by muse, mutect2, varscan2
- MC3R | c.66A>G p.Q22= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs779044626, COSV99710845; called by muse, varscan2
- NCBP1 | c.2025T>C p.D675= | Silent (SNP) | VAF 42/87 reads (48%) | catalogued as COSV100910650, COSV64307682; called by muse, mutect2, varscan2
- NETO1 | c.165T>C p.S55= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as COSV100199698; called by muse, mutect2, varscan2
- OR9I1 | c.72G>A p.E24= | Silent (SNP) | VAF 37/143 reads (26%) | catalogued as COSV100110083, COSV56927242; called by muse, mutect2, varscan2
- POGLUT1 | c.906T>C p.Y302= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV99809834; called by muse, mutect2, varscan2
- POLB | c.609A>G p.E203= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV99613456; called by muse, mutect2, varscan2
- SGSH | c.1005C>A p.I335= | Silent (SNP) | VAF 261/969 reads (27%) | catalogued as COSV100413591; called by muse, mutect2, varscan2
- SLC38A8 | c.99C>T p.L33= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs766376941, COSV100230732; called by muse, mutect2, varscan2
- SLCO4C1 | c.435C>A p.G145= | Silent (SNP) | VAF 88/315 reads (28%) | catalogued as COSV100195802; called by muse, mutect2, varscan2
- SNX1 | c.912A>G p.E304= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs754465239, COSV99976406; called by muse, mutect2, varscan2
- THBS2 | c.1893C>T p.P631= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs748776522, COSV100828074; called by muse, mutect2, varscan2
- TMEM184C | c.1125A>G p.L375= | Silent (SNP) | VAF 64/190 reads (34%) | catalogued as COSV99669802; called by muse, mutect2, varscan2
- TOX2 | c.27C>T p.V9= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs201898502; called by muse, mutect2, varscan2
- UBE3C | c.1935A>T p.P645= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV100780083; called by muse, mutect2, varscan2
- USP8 | c.615A>T p.R205= | Silent (SNP) | VAF 16/196 reads (8%) | catalogued as COSV100209275; called by muse, mutect2
- ZNF587 | c.843C>T p.S281= | Silent (SNP) | VAF 133/219 reads (61%) | catalogued as COSV100299665; called by muse, mutect2, varscan2
- ZNF644 | c.192A>G p.T64= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as COSV100494714; called by muse, mutect2, varscan2
- DCHS2 | n.8537G>T | RNA (SNP) | VAF 25/107 reads (23%) | catalogued as COSV100602606; called by muse, mutect2, varscan2
- TRAPPC10 | c.790+266del | Intron (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- VSIG4 | chrX:66018941 A>G | 3'Flank (SNP) | VAF 76/111 reads (68%) | called by muse, mutect2, varscan2
- ZNF271P | n.1142A>G | RNA (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2, varscan2
